Gene-level copy-number profile of tumor specimen TCGA-BT-A20R-01A from TCGA case TCGA-BT-A20R, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Trigone of bladder; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 79.4 years (28,987 days).
Specimen TCGA-BT-A20R-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.4df11231-2fa2-4c96-9196-2bd7347ccb64.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BT-A20R-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2123a633-630e-460a-91fa-217fb6cf74e4

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 15; copy number 1: 504; copy number 2: 6; copy number 3: 10,927; copy number 4: 28,645; copy number 5: 6,577; copy number 6: 10,715; copy number 7: 69; copy number 8: 655; copy number 9: 708; copy number 10: 107; copy number 11: 187; copy number 12: 229; copy number 15: 300; copy number 16: 87; copy number 18: 26; copy number 22: 17; copy number 26: 19; copy number 34: 20.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BT-A20R-01A-12D-A16M-01): tumor purity 0.46, ploidy 3.07, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 15 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:81,426,393–82,384,027, 12 genes (within-gene range 0–2): RASGEF1B, MTCYBP44, COX5BP1, AC021863.1, NPM1P41, HNRNPA3P13, RNU6-499P, BIN2P1, VAMP9P, AC124016.2, HNRNPD, AC124016.1.
- chr4:90,682,996–91,112,790, 3 genes: AC093729.1, TMSB4XP8, AC004054.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,700 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:39,838,110–40,257,967, 14 genes, copy number 9: TRIT1, Y_RNA, MYCL, MYCL-AS1, Y_RNA, MFSD2A, AL663070.1, CAP1, PPT1, OAZ1P1, RLF, RNU6-1237P, TMCO2, AL050341.2.
- chr1:40,262,672–40,262,984, 1 gene, copy number 9: AL050341.1.
- chr6:11,709,819–15,113,221, 46 genes, copy number 11–22: AL022724.1, ADTRP, AL022724.3, AL022724.2, AMD1P4, AL157373.1, AL157373.2, HIVEP1, EDN1, SUMO2P12, RN7SKP293, RPL15P3, LINC02530, PHACTR1, RNU1-11P, AL008729.1, TBC1D7, AL008729.2, GFOD1, GFOD1-AS1, RPS4XP7, RN7SKP204, SIRT5, AL441883.1, NOL7, RANBP9, Z93020.1, MCUR1, AL023583.1, RNF182, MRPL35P1, AL022396.1, CD83, AL133259.1, RNU7-133P, AL353152.2, AL353152.1, LINC01108, AL080313.2, AL080313.1, AL009177.1, AL109914.1, RNU6-793P, AL138720.1, AL050335.1, RN7SL332P.
- chr6:19,323,428–19,839,080, 1 gene, copy number 26 (within-gene range 7–26): LNC-LBCS.
- chr6:19,438,283–28,491,661, 267 genes, copy number 12–34 (broad region; genes not listed).
- chr6:30,688,047–31,558,829, 80 genes, copy number 16 (broad region; genes not listed).
- chr6:31,718,594–31,726,714, 1 gene, copy number 10 (within-gene range 3–10): MPIG6B.
- chr6:31,727,038–33,192,499, 106 genes, copy number 10 (broad region; genes not listed).
- chr10:44,712–38,783,108, 675 genes, copy number 9 (broad region; genes not listed).
- chr18:32,124,877–34,226,429, 25 genes, copy number 9–16 (within-gene range 6–16): GAREM1, RNA5SP453, MEP1B, CLUHP6, AC015563.1, Y_RNA, AC015563.2, HNRNPA1P7, AC025887.2, WBP11P1, AC009835.1, AC025887.1, KLHL14, AC012123.1, AC012123.2, AC090371.2, CCDC178, AC090371.1, AC091198.1, ASXL3, NOL4, Y_RNA, AC104985.3, AC104985.1, AC104985.2.
- chr19:35,545,600–44,726,058, 484 genes, copy number 11–15 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 504. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
